Gene-level copy-number profile of tumor specimen TCGA-21-5783-01A from TCGA case TCGA-21-5783, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 76.4 years (27,904 days).
Specimen TCGA-21-5783-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.d0e37064-e48c-490a-b3aa-4351d541893f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-21-5783-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3f159eb6-d9d3-4536-94f0-2c666b7c4aa8

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 1,170; copy number 2: 13,277; copy number 3: 30,185; copy number 4: 9,398; copy number 5: 2,870; copy number 6: 649; copy number 7: 438; copy number 8: 934; copy number 9: 133; copy number 10: 35; copy number 13: 710.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-21-5783-01A-41D-2183-01): tumor purity 0.57, ploidy 3.34, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:72,274,552–72,275,159, 1 gene: GDI2P2.
- chr1:72,301,472–72,301,829, 1 gene: RPL31P12.
- chr8:3,373,353–3,375,226, 1 gene (within-gene range 0–1): AC026991.1.
- chr8:3,700,492–4,503,392, 3 genes: RNA5SP251, AC027251.1, AC010941.1.
- chr11:80,321,620–81,040,236, 6 genes (within-gene range 0–2): AP006295.1, RNU6-544P, ARL6IP1P3, LINC02720, AP003398.1, AP003398.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,250 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:38,814–22,548,800, 335 genes, copy number 7 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 13 (broad region; genes not listed).
- chr6:9,596,110–11,044,305, 35 genes, copy number 10 (within-gene range 2–10): OFCC1, AL136226.1, AL354868.1, RNU6ATAC21P, AL138885.1, TFAP2A, TFAP2A-AS2, TFAP2A-AS1, AL138885.2, AL138885.3, LINC00518, MIR5689HG, MIR5689, MRPL48P1, LINC02522, GCNT2, AL139039.3, AL139039.1, AL139039.2, GCNT2P1, AL358777.3, C6orf52, Y_RNA, PAK1IP1, TMEM14C, AL024498.1, TMEM14B, AL024498.2, RNA5SP203, MAK, GCM2, AL357497.1, SYCP2L, ELOVL2, AL121955.1.
- chr6:19,143,695–20,334,411, 16 genes, copy number 7: AL589647.1, AL357052.1, LNC-LBCS, RPL5P20, RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL022726.1, AL008627.1, MBOAT1, AL158198.1, AL158198.2, AL132775.1, AL132775.2.
- chr8:36,308,245–37,095,390, 12 genes, copy number 9: AP006245.1, RNU6-533P, AP006245.2, AC090809.1, RPL23P10, RNA5SP264, KCNU1, AC124076.1, TPT1P8, AC090453.1, AC092818.1, SMARCE1P4.
- chr8:71,828,167–72,118,393, 1 gene, copy number 8 (within-gene range 5–8): MSC-AS1.
- chr8:71,895,991–103,298,772, 534 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr8:103,371,538–118,111,826, 127 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr8:118,620,498–132,760,712, 208 genes, copy number 7–9 (within-gene range 4–9) (broad region; genes not listed).
- chr8:132,866,958–145,066,685, 272 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,165. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
